Gene-level copy-number profile of tumor specimen ALCH-B34Y-TTP1-A from ALCHEMIST case ALCH-B34Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.5 years (25,376 days).
Specimen ALCH-B34Y-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6ac45deb-b1dc-4aec-9df5-11aecadbc15b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B34Y-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/fc58f886-6abd-4c57-b712-626395bd6048

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 26; copy number 2: 4,743; copy number 3: 7,123; copy number 4: 39,730; copy number 5: 1,644; copy number 6: 5,553; copy number 7: 73; copy number 8: 5; copy number 10: 1; copy number 13: 1.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:91,578,478–91,580,863, 2 genes: AC233266.1, AC233266.2.
- chr12:27,824,207–27,824,382, 1 gene: AC009511.3.
- chr14:18,333,726–18,341,859, 1 gene: CR383658.1.
- chr14:100,814,491–100,829,454, 3 genes (within-gene range 0–4): MIR2392, AL117190.5, AL117190.7.
- chr16:75,218,988–75,268,053, 4 genes: CTRB1, AC009078.2, BCAR1, AC009078.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 10: RPL23AP88.
- chr21:8,603,547–8,603,984, 1 gene, copy number 13: RPSAP68.

Autosomal genes at a single copy (total copy number 1): 20. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
